Gene-level copy-number profile of tumor specimen SM-JU34T from CPTAC case C621273, project CPTAC-3 (Colon — Epithelial Neoplasms, NOS). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Colon, NOS.
Specimen SM-JU34T: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9a451839-3a4b-4dea-af0b-3338a105a9c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105218 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/78535cc4-2cc5-471f-9fe8-084fff02a38a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 72; copy number 2: 54,738; copy number 3: 3,582; copy number 4: 10; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:48,810,701–48,811,909, 1 gene, copy number 5 (within-gene range 3–5): AC012379.2.

Autosomal genes at a single copy (total copy number 1): 72. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
